Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A3FW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A3FW-01A (Primary Tumor).

[page 1 of 4]
FINAL LAB RESULTS FROM

Name: _____ Age: _____ MRN or ID: _____
Address: _____ Born: _____
Home: _____ Sex: F
Work: _____

Ordered by:

Attending:

Referring:

Surgical Pathology Report

Sample taken on

Surgical Pathology Report

Accession Number

Collected Date/Time

Received Date/Time

Diagnosis

1) Uterus, cervix, ovaries, and left fallopian tube, hysterectomy

- Endometrial adenocarcinoma, endometrioid type, FIGO grade 3, with superficial myometrial invasion into inner one-half of myometrium (depth of invasion 4 mm; thickness of myometrium 1.5 cm; 27% of myometrial thickness).
- Cervix free of tumor.
- Adenomyosis, leiomyomata.
- Ovaries, bilateral, negative for malignancy.
- Left fallopian tube, negative for malignancy.
- Right fallopian tube not identified (clinical correlation advised).
- 2) Right pelvic lymph nodes, excision:
- Six (6) lymph nodes, negative for malignancy.
- Nodule of remote fat necrosis (incidental finding).
- 3) Left pelvic lymph nodes, excision:
- Six (6) lymph nodes, negative for malignancy.

CAP CANCER CASE SUMMARY CHECKLIST

1: Endometrium, Hysterectomy, Macroscopic

SPECIMEN TYPE:

Hysterectomy

TUMOR SIZE:

Greatest dimension: 3 cm

OTHER ORGANS PRESENT:

Right ovary

Left ovary

Left fallopian tube

1: Endometrium, Hysterectomy, Microscopic

HISTOLOGIC TYPE:

Endometrioid adenocarcinoma, not otherwise characterized

Check	Yes	No
HPV Discrepancy		
Reviewed Initials:	hw	

1CD-0-3

adenocarcinoma, endometrioid, Nos 8380j3

Site: Endometrium C54.1

hw
11/29/11

[page 2 of 4]
HISTOLOGIC GRADE:

G3: More than 50% nonsquamous solid growth

MYOMETRIAL INVASION:

Invasion present

Specify depth of invasion: 4 mm

Specify myometrial thickness: 15 mm

PRIMARY TUMOR (pT):

half pT1b [IB]: Tumor confined to corpus uteri: Tumor invades less than one-half of the myometrium

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis

Number examined: 12

Number involved 0

DISTANT METASTASIS (pM):

PMX: Cannot be assessed

MARGINS:

Uninvolved by invasive carcinoma

(Electronically signed by)

Verified:

Comment

There is a mixture of FIGO grade 2 and FIGO grade 3 tumor present. Although the grade 3 component appears to represent slightly less than 50% of the tumor sampled, there is a significant amount of grade 3 tumor present as well as nuclear grade 3, warranting an overall grade of 3. The pelvic washing ([REDACTED]) shows rare atypical cells but no diagnostic cytologic evidence of malignancy (clinical correlation recommended).

Clinical Information

Endometrial cancer; [REDACTED]

Frozen Section Diagnosis

Intraoperative consultation: Polypoid tumor. No definite invasion identified./

Gross Description

Part 1) Received fresh labeled with the patient's name and "cervix, uterus, bilateral tubes and ovaries" is a pear-shaped uterus with attached cervix, left fallopian tube, and bilateral ovaries. Right fallopian tube is grossly not identified. Uterus and cervix together weigh 86 gm and measure 7.5 x 4.5 x 4 cm. Uterine serosa is tan-pink and smooth. Cervix measures 3.5 cm in diameter and shows no focal lesions. Uterus and cervix are bivalved,

[page 3 of 4]
revealing pale red-tan polypoid tumor in the endometrial cavity measuring 3 x 2 cm in surface dimension located 5.5 cm from the ectocervix. The remaining unremarkable endometrium is tan-red and measures 0.1 cm in thickness. Endocervical canal shows no focal lesions. Sections through the tumor show an irregular endomyometrial junction. No definite invasion is identified grossly (see microscopic description). The myometrium shows apparent adenomyosis and a few unremarkable small leiomyomata ranging up

to

1.5 cm in diameter. Intraoperative report is given to [REDACTED] as indicated above, by [REDACTED]. Representative sections of tumor are submitted for [REDACTED] studies. The left ovary measures 2.5 x 1 x 1 cm and appears unremarkable. The left fallopian tube measures 5 cm in length and 0.5 cm in diameter and appears unremarkable. Representative sections are submitted for [REDACTED] studies. The right ovary measures 3 x 1.5 x 1 cm and appears unremarkable. Representative sections are submitted labeled as follows:

- A: Anterior cervix
- B: Posterior cervix
- C-I: Uterine corpus tumor and leiomyomata
- J,K: Lower uterine segment
- L: Left tube and ovary
- M: Right ovary./[REDACTED]

Part 2) Received fresh labeled with the patient's name and "right pelvic lymph nodes" are several pieces of fibrofatty tissue measuring 3 x 3 x 2

in aggregate. Serial sections show six apparent lymph nodes. Also noted is an ovoid hard nodule suggestive of calcified fat necrosis measuring 1.0 cm in diameter. The lymph nodes are entirely submitted labeled as follows:

- A,B: Trisected one lymph node per cassette.
- C: Bisected lymph node.
- D: Possible three lymph nodes.
- E: Nodule./[REDACTED]

Part 3) Received fresh labeled with the patient's name and "left pelvic lymph nodes" are several pieces of fibrofatty tissue measuring 4 x 3 x 2

in aggregate. Serial sections show six apparent lymph nodes. The lymph nodes are entirely submitted labeled as follows:

- A,B: Bisected one lymph node per cassette.
- C: Trisected largest lymph node.
- D: Bisected lymph node.
- E: Possible remaining two lymph nodes./[REDACTED]

Microscopic Description

Sections show endometrioid adenocarcinoma with glandular (FIGO grade 2)

[page 4 of 4]
and

solid (FIGO grade 3) growth patterns. The solid growth pattern appears to represent slightly less than 50% of the tumor by volume. Due to the nuclear grade 3 in these solid areas, as well as the significant amount of grade 3 tumor, the tumor is classified as FIGO grade 3. There is superficial myometrial invasion present (maximum depth 4 mm; depth of myometrium 1.5 cm; slide D). The lymph node sections show no evidence of metastatic tumor.

Date/time of :

1
A
2

Source: NCI Genomic Data Commons file 2f6abf45-0423-4a87-abed-047b07007bc9 (TCGA-AX-A3FW.AAB4F0FC-D6D5-4D5F-B36C-E4D4869E1A15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).